Somatic mutation profile of tumor specimen MP2PRT-PATBWR-TBP1-A (aliquot MP2PRT-PATBWR-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATBWR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,707 days).
Specimen MP2PRT-PATBWR-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16387a60-01ef-4466-9173-e3fb9fbc3443.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBWR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBWR-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a01ea29e-5dfa-4c04-a058-26c66fd7fd20

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42BPG | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 42/656 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1015957428; called by muse, mutect2
- FBN1 | c.3346G>T p.E1116* | Nonsense Mutation (SNP) | VAF 24/264 reads (9%) | catalogued as COSV57321306; called by muse, mutect2
- H3C7 | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV55099454; called by muse, mutect2
- HOXA1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 60/461 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs763360242, COSV56065234; called by muse, mutect2, varscan2
- LRRTM4 | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273081450; called by muse, mutect2, varscan2
- NTF4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 79/536 reads (15%) | catalogued as rs369788069; called by muse, mutect2, varscan2
- PDE4A | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 97/635 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1424575157; called by muse, mutect2, varscan2
- PLIN5 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 98/635 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1254331301; called by muse, mutect2, varscan2
- TACC2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 43/613 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100552425; called by muse, mutect2
- ARHGEF19 | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 44/619 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ARHGEF19 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 74/919 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.764); called by muse, mutect2
- CCDC168 | c.10264C>G p.Q3422E | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.112); called by muse, mutect2
- MAB21L1 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 40/536 reads (7%) | called by muse, mutect2
- MVP | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 90/636 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAB2 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 89/647 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM15 | c.1721G>C p.R574T | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.362); called by muse, mutect2
- RC3H1 | c.1335A>T p.K445N | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- RHOBTB1 | c.1335G>C p.L445F | Missense Mutation (SNP) | VAF 63/467 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNPO2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 18/395 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.046); called by muse, mutect2
- TNIK | c.1834C>A p.H612N | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZMPSTE24 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- CHRNG | c.1449C>G p.L483= | Silent (SNP) | VAF 61/542 reads (11%) | called by muse, mutect2, varscan2
- FREM3 | c.4548C>T p.I1516= | Silent (SNP) | VAF 56/443 reads (13%) | catalogued as rs1048381340, COSV61680258; called by muse, varscan2
- PLEKHA6 | c.2847G>A p.K949= | Silent (SNP) | VAF 27/426 reads (6%) | called by muse, mutect2
- ZC3H12D | c.1347C>G p.R449= | Silent (SNP) | VAF 35/1081 reads (3%) | catalogued as rs911423568; called by muse, mutect2
